Somatic mutation profile of tumor specimen ALCH-B2TX-TTP1-A (aliquot ALCH-B2TX-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2TX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,877 days).
Specimen ALCH-B2TX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2d824bb-8440-41a9-ba2b-d720fe7e67a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2TX-NB1-A (Blood Derived Normal), aliquot ALCH-B2TX-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6325a215-3a32-4e23-b26d-38f772fd9669

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD29 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 34/582 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1204906985, COSV99409239; called by muse, mutect2
- IGKV3-11 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 34/1022 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ROBO3 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
